Surgical pathology report (de-identified scan), TCGA case TCGA-H7-8501, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-H7-8501-01A (Primary Tumor).

[page 1 of 9]
Specimen Received:

A: Right buccal lymph node
B: Right level 3 lymph node
C: Right mental nerve
D: Right masseter muscle
E: Right buccal mass
F: Right pterygoid muscle
G: Inferior masseter margin
H: Superior masseter margin
I: Lateral masseter margin
J: Right lingual blood vessel
K: Medial pterygoid
L: Right parotid margin
M: Medial alveolar
N: Right retro trigone (FS)
O: Anterior mandible margin
P: New pterygoid margin
Q: Lateral parotid
R: Right level 1-4 neck dissection
S: Level 1A neck dissection
T: Right maxillary teeth

Final Pathologic Diagnosis:

Buccal mass, right, excision:

Histologic type/grade: Keratinizing squamous cell carcinoma,
moderately to poorly differentiated

Tumor size: 6.8 x 5 x 2.3 cm (greatest dimensions)

Depth of invasion: 2.3 cm (greatest dimension)

Lymph-vascular invasion: Present

Perineural invasion: Present

Tumor site: Right buccal mucosa

Tumor focality: Single focus with metastasis to level 1b lymph
node.

Margins:

Margins uninvolved by invasive carcinoma

Distance from closest margin: 0.5 cm

Specify margin(s), per orientation:

Superior aspect of specimen

Margins uninvolved by carcinoma in situ

Lymph nodes, extranodal extension: One lymph node positive for
metastatic squamous cell carcinoma

No extranodal extension

[page 2 of 9]
Pathologic Staging (pTNM):

TNM descriptors: None known

Primary tumor (pT): pT4a

Regional lymph nodes (pN): pN1

Number examined: 43 (includes nodes from parts A, B, Q, R, and S.)

Number involved: 1

Size of the largest positive lymph node: 2.4 cm (greatest dimension)

Distant metastasis (pM): pM-N/A

Additional pathologic findings: None

Specimen: Buccal mucosa, soft tissue along with skin with vermillion component.

Received: In formalin

Procedure: Resection of buccal mass with right neck dissection

Specimen size: 12 x 7.5 x 7 cm (greatest dimensions)

Specimen laterality: Right

A. Lymph node, right buccal, biopsy for frozen section (FSA):

One lymph node, negative for malignancy (0/1).

Frozen section diagnosis confirmed.

B. Lymph node, right level 3, biopsy:

One lymph node, negative for malignancy (0/1).

C. Mental nerve, right, biopsy for frozen section ()

Negative for malignancy.

Frozen section diagnosis confirmed.

D. Masseter muscle, right, biopsy for frozen section ()

Negative for malignancy.

Frozen section diagnosis confirmed.

E. Buccal mass, right, resection:

Poorly differentiated squamous cell carcinoma (see Synoptic Report above).

F. Pterygoid muscle, right, biopsy for frozen section ()

Negative for malignancy.

Frozen section diagnosis confirmed.

G. Masseter margin, inferior, biopsy for frozen section ()

Negative for malignancy.

Frozen section diagnosis confirmed.

H. Masseter margin, superior, biopsy for frozen section ()

[page 3 of 9]
Negative for malignancy.
Frozen section diagnosis confirmed.

I. Masseter margin, lateral, biopsy for frozen section ([REDACTED])
Negative for malignancy.
Frozen section diagnosis confirmed.

J. Lingual blood vessel, right, biopsy for frozen section ([REDACTED])
Negative for malignancy.
Frozen section diagnosis confirmed.

K. Pterygoid, medial, biopsy for frozen section ([REDACTED])
Negative for malignancy.
Frozen section diagnosis confirmed.

L. Parotid margin, right, biopsy for frozen section ([REDACTED])
Negative for malignancy.
Frozen section diagnosis confirmed.

M. Medial alveolar, biopsy for frozen section ([REDACTED])
Negative for malignancy.
Frozen section diagnosis confirmed.

N. Retrotrigone, right, biopsy for frozen section ([REDACTED])
Negative for malignancy.
Frozen section diagnosis confirmed.

O. Mandible margin, anterior, biopsy:
Negative for malignancy.

P. Pterygoid margin, new, biopsy for frozen section ([REDACTED])
Negative for malignancy.
Frozen section diagnosis confirmed.

Q. Lateral parotid, biopsy:
Five lymph nodes negative for malignancy (0/5).

R. Lymph nodes, level 1-4, right, neck dissection:
One of thirty two lymph nodes positive for metastatic squamous cell carcinoma, 2.4 cm maximum dimension.
Level IA: (0/3)
Level IB: (1/4)
Level II: (0/6)
Level III: (0/3)
Level IV: (0/16)
Submandibular gland without pathologic change.

S. Lymph nodes, level 1A, neck dissection:
Four lymph nodes negative for malignancy.

[page 4 of 9]
T. Maxillary teeth, right, extraction:
Maxillary teeth with dental restorations (gross only).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA: Right facial lymph node:
One lymph node negative for malignancy.
TAT: 7 mins.

FSC: Right mental nerve:
Negative for malignancy.

FSD: Right masseter muscle:
Negative for malignancy.

FSF: Right pterygoid muscle:
Detached necrotic squamous debris.

FSC-FSF TAT:

FSG: Inferior masseter margin:
Negative for malignancy.

FSH: Superior masseter margin:
Negative for malignancy.

FSI: Lateral masseter margin:
Negative for malignancy.

FSJ: Right lingual blood vessel:
Negative for malignancy.

FSK: Medial pterygoid:
Negative for malignancy.

FSL: Right parotid margin:
Negative for malignancy.

FSM: Medial alveolar:
Negative for malignancy.

FSN: Right retro trigone:
Negative for malignancy.

FSP: New pterygoid margin:
Negative for malignancy.

[page 5 of 9]
FSG-FSP TAT: 37 mins.

Gross Description:

Received are twenty specimen containers, all labeled with the patient name.

Part A is received additionally labeled "right facial lymph node (FSA)." The specimen consists of predominately yellow lobulated fibrofatty tissues having aggregate dimensions of 1.5 x 1 x 0.3 cm. Within these tissues there is a single lymph node candidate which is submitted for frozen section evaluation (FSA) with residual frozen section tissue submitted in cassette A.

Part B is received in formalin and additionally labeled, "right Level III lymph node" and consists of a single nodular portion of pink-tan soft tissue grossly consistent with lymph node having a dimension of 1 x 0.8 x 0.8 cm. This lymph node is bisected and submitted entirely in cassette B.

Part C is received fresh for frozen section evaluation additionally labeled, "right mental nerve (FSC)" and consists of a single 4 mm in greatest dimension gray-tan irregular soft tissue which is submitted for frozen section evaluation (FSC)" with residual frozen section tissue submitted in cassette C.

D is received fresh for frozen section evaluation additionally labeled, "right masseter muscle (FSD)" and consists of multiple fragments of red-brown apparent skeletal muscle having aggregate dimensions of 2 x 1.7 x 0.3 cm submitted for frozen section evaluation (FSD) with residual frozen section tissue submitted in cassette D.

Part E is received in formalin additionally labeled, "right buccal mass" and consists of a 12 x 7.5 by up to 7 cm portion of pink-tan to red-brown soft tissue consisting of skeletal muscle, apparent buccal mucosa and being partially surfaced by an ovoid portion of skin with vermillion component. The skin with the vermillion component has dimensions of 9.5 x 6 cm and the vermillion component has dimensions of 3 x 1.5 x 1 cm.

The buccal mucosa is remarkable for a large centrally ulcerated mass which is 6.8 x 5 cm ulcerated to a depth of up to 2.3 cm. The skin bearing component is essentially unremarkable with the exception of a suggestion of submucosal tumor extension to the proximal pole of the vermillion border (see gross photo). The entire circumferential aspect of the specimen is surfaced by tissues which are uninvolved by this tumor. The superior aspect of the specimen is inked in yellow, inferior aspect is inked green, the superficial aspect not surfaced by skin is inked blue. The proximal aspect is inked red. The distal aspect is inked red on black and the deep aspect is inked black. Those portions of the specimen surfaced by mucosa and/or skin remain un-inked. Please note, these inked regions do not represent true margins (see frozen sections). There is no bony component identified with this specimen.

[page 6 of 9]
The specimen is subsequently step-sectioned proximal to distal to reveal a large centrally necrotic tan-white mass subjacent to the previously described region of ulceration which has overall dimensions of 8 x 6 x 5 cm. Additionally this lesion approaches to within 0.8 cm of the inferior aspect of the specimen, 0.5 cm of the superior aspect of the specimen and to within 3.5 cm of the proximal skeletal muscle margin of surgical resection and 1 cm of the distal margin of surgical resection. Additionally this mass courses beneath the more proximal aspect of the vermillion border (see cassette E1) and infiltrates the fatty tissues with limited necrosis (see cassette E5).

Representative sections of "mass" are submitted in cassettes E1-E5.

Also received in the same container is an additional 2 x 1.5 x 1 cm of tan-brown nodular soft tissue possibly representing lymph node which is bisected and submitted in cassette E6.

Part F is received fresh for frozen section evaluation additionally labeled, "right pterygoid muscle (FSF)" and consists of 1.8 x 1 x 0.3 cm of red-brown irregular soft tissue which is submitted for frozen section evaluation (FSF) with residual frozen section tissue submitted in cassette F.

Part G is received fresh for frozen section evaluation additionally labeled, "inferior masseter margin (FSG)" and consists of 2.5 x 1.5 x 0.3 cm of red-brown skeletal muscle which is submitted for frozen section evaluation (FSG) with residual frozen section tissue submitted in cassette G.

H is received fresh for frozen section evaluation additionally labeled, "superior masseter margin (FSH)" and consists of a 0.8 x 0.6 x 0.3 cm of fragmented tan-yellow irregular soft tissue which is submitted for frozen section evaluation (FSH) with residual frozen section tissue submitted in cassette H.

Part I is received fresh for frozen section evaluation additionally labeled, "lateral masseter margin (FSI)" and consists of multiple fragments of tan-yellow irregular soft tissue 1.5 x 1 x 0.3 cm submitted for frozen section evaluation (FSI) with residual frozen section tissue submitted in cassette I.

Part J is received fresh for frozen section evaluation additionally labeled, "right lingual blood vessel" and consists of a single portion of tan-white irregular soft tissue which is 0.6 x 0.5 x 0.2 cm submitted for frozen section evaluation (FSJ)" with residual frozen section tissue submitted in cassette J.

Part K is received fresh for frozen section evaluation additionally labeled, "medial pterygoid (FSK)" and consists of a 1 x 0.7 x 0.4 cm portion of red-brown soft tissue submitted for frozen section evaluation (FSK) with residual frozen section tissue submitted in cassette K.

Part L is received fresh for frozen section evaluation additionally labeled, "right parotid margin (FSL)" and consists of a 1.3 x 0.8 x 0.4 cm portion of

[page 7 of 9]
tan-yellow irregular soft tissue submitted for frozen section evaluation (FSL) with residual frozen section tissue submitted in cassette L.

Part M is received fresh for frozen section evaluation additionally labeled, "medial alveolar margin (FSN)" and consists of a strip of tan-yellow soft tissue which is 1.2 x 0.2 x 0.2 cm submitted for frozen section evaluation (FSM) with residual frozen section tissue submitted in cassette M.

Part N is received fresh for frozen section evaluation additionally labeled, "right retromolar trigone (FSN)" and consists of a single tan-yellow nodular soft tissue which is 0.9 x 0.8 x 0.3 cm submitted for frozen section evaluation (FSN) with residual frozen section tissue submitted in cassette N.

Part O is received in formalin additionally labeled, "anterior mandible margin" and consists of a portion of firm white bone which is 2 x 0.6 x 0.5 cm submitted in toto in cassette O following decalcification.

Part P is received fresh for frozen section evaluation additionally labeled, "new margin pterygoid" and consists of multiple fragments of red-brown irregular soft tissues having aggregate dimensions of 2.2 x 1.8 x 0.3 cm. These tissues are submitted for frozen section evaluation (FSP) with residual frozen section tissue submitted in cassette P.

Part Q is received in formalin additionally labeled, "lateral parotid" and consists of multiple fragments of pink-tan irregular soft tissues admixed with fibrofatty tissues all of which have aggregate dimensions of 4.5 x 3 x 2 cm. There is no additional orientation offered or possible with this fragmented specimen. The parotid gland portion of the specimen features yellow lobulated architecture without distinct masses. Sectioning through the additional soft tissues reveals multiple probable lymph nodes (six) that range from 0.4 to 1.4 cm in greatest dimension. The tissues are submitted as follows:

- Q1 essentially unremarkable salivary gland;
- Q2 four whole probable lymph nodes;
- Q3,4 one whole lymph node each cassette each bisected.

Part R is labeled "right level 1-4 neck dissection, double stitch on 4." The specimen consists of a portion of yellow-tan to red-tan fibroadipose and fibromuscular tissue received with two sutures designated level 4. The specimen has overall dimensions of 13.5 x 8 by up to 2.8 cm. The specimen is divided into levels 1A and 1B, 2, 3 and 4. There is a salivary gland in level 1A that has dimensions of 5 x 2.5 by up to 1.2 cm. Sectioning through the salivary gland reveals a pink-tan, lobulated cut surface. Sectioning through the remaining level 1A reveals three additional lymph nodes up to 1 cm.

The sections from level 1A are submitted as follows:

- R1 salivary gland;
- R2 two whole lymph nodes;
- R3 one lymph node bisected.

[page 8 of 9]
Sectioning through level 1B reveals five lymph nodes, which range from 0.5 x 0.4 x 0.4 cm up to 4 x 2.5 x 2.2 cm. The largest lymph node has a tan-white, degenerative suspicious cut surface. The suspicious lymph node approaches the interface of the salivary gland in level 1A.

The lymph nodes from level 1B are submitted as follows:

- R4 one cross section from suspicious lymph node;
- R5 two whole lymph nodes;
- R6 one lymph node bisected.

Sectioning through level 2 reveals a few lymph nodes up to 0.6 cm in greatest dimension. These lymph nodes are submitted as follows:

- R7 multiple whole lymph nodes;
- R8 one lymph node bisected.

Sectioning through level 3 reveals three lymph nodes up to 2.2 cm in greatest dimension. These lymph nodes are submitted as follows:

- R9 one lymph node bisected;
- R10 one lymph node bisected;
- R11 one lymph node bisected.

Sectioning through level 4 reveals multiple lymph nodes up to 1.1 cm in greatest dimension. These lymph nodes are submitted as follows:

- R12-13 multiple whole lymph nodes;
- R14-16 each with one lymph node sectioned.

Part S is received in formalin additionally labeled, "Level 1A neck dissection" and consists of multiple fragments of tan-yellow soft tissue having aggregate dimensions of 3 x 2 x 1 cm. There is no orientation offered or possible with these tissues. By palpation there are two probable lymph nodes 0.5 and 0.7 cm in greatest dimension both of which are submitted in cassette S1. The remaining tissues are submitted entirely in cassette S2 and S3.

Part T is additionally labeled, "right maxillary teeth" and consists of three partially fragmented carious teeth some of which have indwelling amalgams and are consistent with bicuspid as well as two molars having dimensions of 2.2 x 1 x 0.8 cm, 2.2 x 1.4 x 0.9 cm and 2.5 x 1.4 x 0.8 cm respectively. No sections are submitted on these gross only tissues. This portion of the case has been reviewed by staff pathologist

Microscopic Description:

The histologic evaluation of the specimen demonstrates a poorly differentiated keratinizing squamous cell carcinoma that arises from the buccal mucosa. The tumor is composed of malignant pleomorphic cells arranged in sheets and nest with squamous pearls of keratin in the more well-differentiated areas. The tumor infiltrates through the muscles of the buccal mucosa into the soft tissue of the skin and abuts the mucosa at the vermilion boarder of the lip. The tumor does not extend to the surface of the skin. The tumor involves nerves with areas of angiolymphatic invasion. The surgical resection margins are negative.

[page 9 of 9]
There is a single lymph node positive for metastatic keratinizing squamous cell carcinoma in slide R4.

END OF REPORT

Source: NCI Genomic Data Commons file ac9ed2ac-f5ba-4f1d-9b56-03f1e64e59ff (TCGA-H7-8501.5C97728B-EFAA-4506-BD02-B3A34C518127.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).